Somatic mutation profile of tumor specimen C3L-06922-01 (aliquot CPT0423240006) from CPTAC case C3L-06922, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 53.2 years (19,439 days).
Specimen C3L-06922-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fcf6207-464d-4e49-85cf-64a40cf5258e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06922-31 (Blood Derived Normal), aliquot CPT0423230005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f15c6a9-b6b1-42de-8145-b46d4547ac43

The open-access MAF lists 106 somatic variants for this specimen: 80 protein-altering or splice-affecting, 20 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 20, Nonsense Mutation 6, In Frame Del 3, Frame Shift Del 3, RNA 2, Intron 2, Translation Start Site 2, 3'Flank 1, Splice Site 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 41/218 reads (19%) | catalogued as rs761796175, COSV55096068; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.30_53del p.W11_P18del | In Frame Del (DEL) | VAF 38/181 reads (21%) | hotspot (GDC flag); catalogued as COSV55995640; called by mutect2, pindel, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 74/236 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 79/238 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.4213G>A p.D1405N | Missense Mutation (SNP) | VAF 62/290 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1390869641, CM077911; called by muse, mutect2, varscan2
- ADAM2 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs141797246; called by muse, mutect2, varscan2
- ARHGEF3 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 151/311 reads (49%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs778808215; called by muse, mutect2, varscan2
- ARID1A | c.4582C>T p.R1528* | Nonsense Mutation (SNP) | VAF 61/306 reads (20%) | catalogued as COSV100251965, COSV61372105; called by muse, mutect2, varscan2
- ARID1A | c.6562C>T p.Q2188* | Nonsense Mutation (SNP) | VAF 92/390 reads (24%) | catalogued as COSV61374926; called by muse, mutect2, varscan2
- C1QL4 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 109/447 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs776540032; called by muse, mutect2, varscan2
- CDH8 | c.1808G>A p.G603D | Missense Mutation (SNP) | VAF 110/415 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54904948; called by muse, varscan2
- COPZ1 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 41/216 reads (19%) | catalogued as rs1343279456; called by muse, mutect2, varscan2
- CTTNBP2 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs747316797, COSV50394511; called by muse, mutect2, varscan2
- DACT1 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 102/424 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60019815; called by muse, mutect2, varscan2
- DAP3 | c.844-1G>T p.X282_splice | Splice Site (SNP) | VAF 50/203 reads (25%) | catalogued as COSV58019599; called by muse, mutect2, varscan2
- DHH | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57202007; called by muse, mutect2, varscan2
- EID1 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.744); catalogued as COSV100194706; called by muse, mutect2, varscan2
- ERC1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 81/341 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs535851221, COSV61697579; called by muse, mutect2, varscan2
- EXOC3L2 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 95/374 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1363468004, COSV99374507; called by muse, mutect2, varscan2
- FAF1 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 70/347 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1026361660; called by muse, mutect2, varscan2
- GFI1 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 81/324 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as COSV54042846, COSV54042931; called by muse, varscan2
- HS3ST4 | c.1335A>C p.Q445H | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.981); catalogued as COSV58803837, COSV58808981; called by muse, mutect2, varscan2
- KIF19 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as rs756060744; called by muse, mutect2, varscan2
- LDB3 | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 74/284 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs754529329, COSV53948758; called by muse, varscan2
- LOXHD1 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs916954027, COSV59662442; called by muse, mutect2, varscan2
- MTOR | c.1174A>G p.I392V | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749850706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC12 | c.953C>T p.T318M (on ENST00000379442; = p.T175M on NM_001164462.1) | Missense Mutation (SNP) | VAF 183/488 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs769176549, COSV65182189; called by muse, mutect2, varscan2
- MYO15A | c.5776C>T p.R1926C | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539637895, COSV52755516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2T35 | c.748G>C p.V250L | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100442212; called by muse, mutect2, varscan2
- OR52R1 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 93/347 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs758370052, COSV61888958; called by muse, mutect2, varscan2
- OR56A4 | c.821C>A p.S274Y | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV100417554, COSV58111654; called by muse, mutect2
- PCSK9 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 68/258 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1302868036; called by muse, mutect2, varscan2
- PIEZO1 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 71/309 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs757100265, COSV56340310; called by muse, mutect2, varscan2
- RCOR2 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs768003765, COSV56850036; called by muse, mutect2, varscan2
- RIPPLY2 | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs745933529; called by muse, mutect2, varscan2
- RTN4RL1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 97/357 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373384654; called by muse, mutect2, varscan2
- SFRP4 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 172/458 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52260324; called by muse, mutect2, varscan2
- SMAD3 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 96/368 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223765, COSV59280349, COSV59288226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTK | c.575dup p.Q193Afs*33 | Frame Shift Ins (INS) | VAF 42/195 reads (22%) | catalogued as rs756799506; called by mutect2, varscan2
- TUBA3E | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 101/256 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs796605338; called by muse, mutect2, varscan2
- UBE2O | c.3671C>G p.P1224R | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs771187543; called by muse, mutect2, varscan2
- UNC5C | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 72/327 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765485658, COSV71661228; called by muse, varscan2
- ZNF420 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs1276971488; called by muse, mutect2
- ZNF467 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 42/602 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs866656193; called by muse, mutect2
- ZNF560 | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 73/323 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142348936; called by muse, mutect2, varscan2
- ZSCAN10 | c.1432C>T p.R478C (on ENST00000252463; = p.R533C on NM_032805.3) | Missense Mutation (SNP) | VAF 87/431 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV99373748; called by muse, mutect2, varscan2
- ACTL9 | c.1154C>G p.S385C | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ARTN | c.649G>A p.G217S (on ENST00000372354; = p.G225S on NM_057090.2) | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- CACNA2D3 | c.962A>T p.E321V | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- CADPS | c.722T>G p.F241C | Missense Mutation (SNP) | VAF 68/321 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CCDC63 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CERKL | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- COLEC11 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 15/386 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.658); called by muse, mutect2
- CSH2 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CTNND1 | c.443_444del p.V148Dfs*24 | Frame Shift Del (DEL) | VAF 33/190 reads (17%) | called by pindel, varscan2
- DYNC1I2 | c.400G>T p.G134* | Nonsense Mutation (SNP) | VAF 42/142 reads (30%) | called by muse, mutect2, varscan2
- ENPEP | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 102/412 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAT3 | c.2353G>C p.V785L | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- FBXL13 | c.1168_1169del p.S390Rfs*11 | Frame Shift Del (DEL) | VAF 44/281 reads (16%) | called by pindel, varscan2
- GRXCR1 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNQ3 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- MAP2K1 | c.169_171del p.K57del | In Frame Del (DEL) | VAF 47/199 reads (24%) | called by mutect2, pindel, varscan2
- MUC5B | c.15803C>T p.P5268L | Missense Mutation (SNP) | VAF 81/324 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- NELFB | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 26/506 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.037); called by muse, mutect2
- NRK | c.3245A>C p.N1082T | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR4D5 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PARD3B | c.727A>G p.K243E | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- PCDH10 | c.2509C>G p.L837V | Missense Mutation (SNP) | VAF 91/344 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PKHD1L1 | c.12686T>A p.F4229Y | Missense Mutation (SNP) | VAF 17/285 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); called by muse, mutect2
- PNOC | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- RBAK | c.832_834del p.I278del | In Frame Del (DEL) | VAF 52/314 reads (17%) | called by pindel, varscan2
- RUNX2 | c.39T>A p.C13* | Nonsense Mutation (SNP) | VAF 44/201 reads (22%) | called by muse, mutect2, varscan2
- SCARA5 | c.493C>A p.Q165K | Missense Mutation (SNP) | VAF 84/434 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SCRN2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 93/353 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SERPINA7 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TECTA | c.4205G>T p.C1402F | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPAN13 | c.27del p.K10Rfs*18 | Frame Shift Del (DEL) | VAF 73/356 reads (21%) | called by mutect2, pindel, varscan2
- TTN | c.27233A>C p.N9078T (on ENST00000591111; = p.N8151T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/255 reads (15%) | PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZBTB42 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 88/365 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIC1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 170/420 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- A2ML1 | c.2274C>T p.D758= | Silent (SNP) | VAF 70/257 reads (27%) | catalogued as rs762980682, COSV100229138; called by muse, mutect2, varscan2
- ADCY8 | c.1752T>G p.T584= | Silent (SNP) | VAF 51/331 reads (15%) | catalogued as COSV53899574, COSV53915819; called by muse, mutect2, varscan2
- AGBL4 | c.741T>A p.L247= | Silent (SNP) | VAF 10/201 reads (5%) | called by muse, mutect2
- DDI1 | c.939C>T p.F313= | Silent (SNP) | VAF 75/286 reads (26%) | catalogued as COSV56389762; called by muse, mutect2, varscan2
- FOXI3 | c.366G>A p.A122= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV101230916; called by muse, mutect2, varscan2
- HELT | c.564G>A p.L188= | Silent (SNP) | VAF 92/431 reads (21%) | called by muse, mutect2, varscan2
- KCND1 | c.300G>A p.T100= | Silent (SNP) | VAF 110/238 reads (46%) | catalogued as rs782248996; called by muse, mutect2, varscan2
- LDOC1 | c.51C>T p.R17= | Silent (SNP) | VAF 70/164 reads (43%) | called by muse, mutect2, varscan2
- MSH6 | c.477C>A p.A159= | Silent (SNP) | VAF 51/249 reads (20%) | catalogued as COSV99317111; called by muse, mutect2, varscan2
- MUC16 | c.11265G>A p.Q3755= | Silent (SNP) | VAF 74/304 reads (24%) | catalogued as COSV67501557; called by muse, mutect2, varscan2
- NPY4R | c.135C>T p.V45= | Silent (SNP) | VAF 96/986 reads (10%) | catalogued as rs1358430214; called by muse, mutect2
- NRG3 | c.114G>A p.P38= | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- OR10G7 | c.441T>C p.T147= | Silent (SNP) | VAF 38/376 reads (10%) | catalogued as COSV57867933; called by muse, mutect2
- PAPOLB | c.45G>A p.A15= | Silent (SNP) | VAF 172/426 reads (40%) | catalogued as COSV68201341; called by muse, mutect2, varscan2
- PCDHB11 | c.402G>A p.S134= | Silent (SNP) | VAF 56/277 reads (20%) | catalogued as rs546425608, COSV53379383; called by muse, mutect2, varscan2
- PLXND1 | c.666G>A p.P222= | Silent (SNP) | VAF 101/550 reads (18%) | called by muse, mutect2, varscan2
- RGL2 | c.1731A>G p.P577= | Silent (SNP) | VAF 90/402 reads (22%) | called by muse, mutect2, varscan2
- SHC2 | c.654C>T p.A218= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as rs149705923; called by muse, mutect2
- STRIP2 | c.2460G>A p.V820= | Silent (SNP) | VAF 93/262 reads (35%) | called by muse, mutect2, varscan2
- ZFHX4 | c.816G>A p.G272= | Silent (SNP) | VAF 38/330 reads (12%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.730dup | RNA (INS) | VAF 36/208 reads (17%) | called by mutect2, pindel, varscan2
- ERN2 | c.-34G>A | 5'UTR (SNP) | VAF 16/432 reads (4%) | called by muse, mutect2
- HSPB11 | chr1:53916838 C>T | 3'Flank (SNP) | VAF 11/157 reads (7%) | called by muse, mutect2
- LINC02363 | n.897C>T | RNA (SNP) | VAF 76/321 reads (24%) | catalogued as rs1023167233; called by muse, mutect2, varscan2
- PXN | c.934-47G>A | Intron (SNP) | VAF 98/371 reads (26%) | catalogued as rs369254372; called by muse, mutect2, varscan2
- SORBS2 | c.-197-5981G>A | Intron (SNP) | VAF 49/207 reads (24%) | catalogued as rs1364401045; called by muse, mutect2, varscan2
